Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A2NB, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A2NB-01A (Primary Tumor).

FINAL DIAGNOSIS:**PART 1: ANUS AND RECTUM, ABDOMINAL PERINEAL RESECTION-**

- A. NODULAR MALIGNANT MELANOMA OF ANUS, BRESLOW DEPTH 10.0 MM (see comment and synoptic report).
- B. TUMOR INVADES MUSCULARIS PROPRIA.
- C. SURFACE ULCER PRESENT.
- D. MITOSES OF 1 PER MM SQUARED.
- E. SURGICAL MARGINS (PROXIMAL, DISTAL, AND RADIAL) FREE OF TUMOR.
- F. HYPERPLASTIC POLYP.
- G. PATHOLOGIC STAGE: ypT4b N2.

PART 2: COLON, PROXIMAL RECTUM, RESECTION-

- A. COLON WITH TWO HYPERPLASTIC POLYPS.
- B. TWO OF TWENTY-ONE LYMPH NODES WITH METASTATIC MELANOMA (2/21), LESS THAN 1 MM EACH.
- C. NO EXTRACAPSULAR SPREAD PRESENT.
- D. SURGICAL MARGINS FREE OF TUMOR.

PART 3: SKIN MARGIN, LEFT CIRCUMFERENTIAL, EXCISION-

- A. SKIN WITH FOCAL ACUTE INFLAMMATION.
- B. NEGATIVE FOR MALIGNANCY.

COMMENT:

The tumor is immunoreactive for S100, MelanA, and Tyrosinase and is negative for cytokeratin AE1/3. These results support melanoma. A left groin lymph node previously excised contains metastatic melanoma. BRAF and KIT testing have been performed previously

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY CUTANEOUS MELANOMA**

TUMOR LOCATION:	Family history of melanoma is unknown.
TYPE OF PROCEDURE:	Family history of dysplastic nevi is unknown.
SIZE OF TUMOR:	Other location: anus
GROSS ULCERATION:	Other: abdominal perineal resection
GROSS SATELLITES:	Maximum surface diameter of neoplasm: 45 mm
HISTOLOGIC TYPE:	Yes
SURFACE ULCERATION:	No
CLARK'S LEVEL:	Nodular
BRESLOW'S THICKNESS:	> 50%
ANGIOLYMPHATIC INVASION:	NA
PERINEURAL INVASION:	10 mm
EVIDENCE OF REGRESSION:	Present
MICROSCOPIC SATELLITES:	No
PREEXISTING NEVUS:	No
TUMOR INFILTRATING LYMPHOID INFILTRATE:	No microscopic satellites
MITOTIC RATE:	No preexisting nevus
VASCULARITY:	None (absent)
SURGICAL MARGIN INVOLVEMENT:	Mitotic rate: 1 / mm squared
SENTINEL LYMPH NODE MAPPING:	Not increased to focally increased
LYMPH NODES EXAMINED:	Deep margin is free of tumor, Lateral margin is free of tumor
COMPLETION DISSECTION:	No
EXTRACAPSULAR SPREAD:	Total number of lymph nodes examined: 21
LYMPH NODES POSITIVE:	No
SIZE OF NODAL METASTASES:	None
T STAGE, PATHOLOGIC:	Number of lymph nodes positive at completion dissection: 2
N STAGE, PATHOLOGIC:	< 2mm
M STAGE, PATHOLOGIC:	pT4b
	pN2
	pMX

ICD-O-3

Melanoma, NOS 8720/3

Site: skin, anus c44.5

/w 8/19/11

Source: NCI Genomic Data Commons file 525ce2be-e77c-4a42-a156-88c1fcaf86b9 (TCGA-ER-A2NB.7A71CD0E-93A6-4AFF-90D7-D40FE351A92D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).